Somatic mutation profile of tumor specimen ALCH-B2MQ-TTP1-B (aliquot ALCH-B2MQ-TTP1-B-12-0-D-A777-36) from ALCHEMIST case ALCH-B2MQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.5 years (27,220 days).
Specimen ALCH-B2MQ-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5662a637-31eb-4b9e-a25d-082e260e4ec9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2MQ-NB1-A (Blood Derived Normal), aliquot ALCH-B2MQ-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b965b326-9320-4445-8114-0b80bf004c65

The open-access MAF lists 256 somatic variants for this specimen: 181 protein-altering or splice-affecting, 47 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 47, Intron 16, Nonsense Mutation 12, 3'UTR 6, Splice Region 4, RNA 3, Frame Shift Ins 3, Splice Site 2, 5'UTR 2, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA1 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 47/269 reads (17%) | catalogued as rs1463885690, CM083070, COSV57192389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 31/168 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM11 | c.2051G>T p.R684L | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV52347819; called by muse, mutect2, varscan2
- ANKRD17 | c.7150G>T p.A2384S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.042); catalogued as COSV58223128; called by muse, varscan2
- APOB | c.13487G>C p.R4496T | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV51922834, COSV51952204, COSV51952606; called by muse, mutect2, varscan2
- C2CD4D | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1164724847; called by muse, mutect2
- CCDC102B | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.325); catalogued as COSV60134667; called by mutect2, varscan2
- CD163 | c.3353A>G p.H1118R | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1379906416; called by muse, mutect2
- CD96 | c.1151C>A p.S384* (on ENST00000283285 / NM_198196.3; = p.S368* on NM_005816.5) | Nonsense Mutation (SNP) | VAF 44/358 reads (12%) | catalogued as COSV99343594; called by muse, mutect2, varscan2
- CDC42BPA | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs1022118984; called by muse, mutect2
- CDH11 | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99218871; called by muse, mutect2
- CHST6 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 87/528 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as rs868114571, COSV60001096; called by muse, mutect2, varscan2
- CHSY1 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs775607768, COSV99573868; called by muse, mutect2, varscan2
- COL11A1 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 36/377 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62189293; called by muse, mutect2
- COL5A3 | c.3314G>A p.R1105Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.152); catalogued as rs578120063, COSV53416066; called by muse, mutect2, varscan2
- CT47B1 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.093); catalogued as rs372326345, COSV100988982; called by muse, mutect2, varscan2
- DCAF17 | c.321+1G>T p.X107_splice | Splice Site (SNP) | VAF 35/339 reads (10%) | catalogued as CS118251; called by muse, mutect2, varscan2
- ELOVL2 | c.653C>A p.T218K | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.169); catalogued as COSV61154096; called by muse, mutect2, varscan2
- FIBCD1 | c.912C>A p.D304E | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs149922280; called by muse, mutect2, varscan2
- FLCN | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM087714, COSV53259642; called by muse, mutect2, varscan2
- GP2 | c.802G>A p.E268K (on ENST00000381362 / NM_001007240.3; = p.E265K on NM_001502.4) | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.099); catalogued as COSV56894470; called by muse, mutect2, varscan2
- GRIP1 | c.1559T>C p.I520T (on ENST00000359742 / NM_001379345.1; = p.I468T on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/513 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs1178422573; called by muse, mutect2, varscan2
- GSR | c.215del p.G72Afs*32 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs1554575680; called by mutect2, varscan2
- GSTO2 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58537791; called by muse, mutect2, varscan2
- H3C10 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV60798085; called by muse, mutect2
- HCN4 | c.3524C>T p.S1175F | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV56088632; called by muse, mutect2, varscan2
- HYDIN | c.1724G>C p.G575A | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99863833; called by muse, mutect2
- KALRN | c.8957C>G p.T2986R (on ENST00000360013 / NM_001024660.4; = p.T1289R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs776926854, COSV99360965; called by mutect2, varscan2
- KEAP1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV50260447, COSV50260545; called by muse, mutect2, varscan2
- KIAA0586 | c.2589G>T p.Q863H (on ENST00000619416 / NM_001244190.2; = p.Q802H on NM_014749.5) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54173972, COSV54174607; called by muse, mutect2, varscan2
- MORC1 | c.2668T>C p.Y890H | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1299330592; called by muse, mutect2, varscan2
- MTERF1 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs546581646, COSV61099097; called by muse, mutect2
- MUC4 | c.12941G>C p.R4314T (on ENST00000463781 / NM_018406.7; = p.R78T on NM_004532.6) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs768733396; called by muse, mutect2
- NEU1 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 65/507 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV57669330; called by muse, varscan2
- NR1H4 | c.368G>T p.R123L (on ENST00000551379 / NM_001206993.2; = p.R113L on NM_005123.4) | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs565451641, COSV51851194, COSV51856053; called by muse, mutect2, varscan2
- OBSCN | c.9445C>T p.R3149W | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as rs748992672; called by muse, mutect2, varscan2
- OR51B2 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.078); catalogued as COSV60915937; called by muse, mutect2, varscan2
- OR52B2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV73209446; called by muse, mutect2, varscan2
- PCDHAC1 | c.1655A>T p.Y552F | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs782813761; called by muse, mutect2, varscan2
- PCDHB2 | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV52030220, COSV52033669; called by muse, mutect2, varscan2
- PDE10A | c.2228A>T p.Q743L | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1435691846; called by muse, mutect2, varscan2
- PDK4 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV50012796; called by muse, mutect2, varscan2
- PKHD1 | c.1836C>A p.H612Q | Missense Mutation (SNP) | VAF 35/436 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs138435568; called by muse, mutect2
- PLXNA4 | c.5531T>A p.F1844Y | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765125797; called by muse, mutect2, varscan2
- PRR36 | c.3614C>T p.S1205L | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs1474597941; called by muse, mutect2, varscan2
- PRSS45P | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs568521205; called by muse, mutect2, varscan2
- PTPRN2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV67034226; called by muse, mutect2, varscan2
- RALYL | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774438419, COSV72823376; called by muse, mutect2, varscan2
- SORBS1 | c.620T>C p.L207P (on ENST00000361941 / NM_001034954.2; = p.L175P on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs979315379; called by muse, mutect2, varscan2
- SORCS3 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 21/301 reads (7%) | catalogued as COSV63802085; called by muse, mutect2
- SPTA1 | c.6052G>T p.E2018* | Nonsense Mutation (SNP) | VAF 22/293 reads (8%) | catalogued as COSV63757762; called by muse, mutect2
- SUSD2 | c.2053G>T p.D685Y | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1229175950; called by muse, mutect2
- TLE3 | c.1858G>T p.G620W | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58173532; called by muse, varscan2
- TMEM132C | c.873C>G p.N291K | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV101473664; called by muse, mutect2, varscan2
- TPTE2 | c.1563G>T p.E521D (on ENST00000400230 / NM_199254.2; = p.E444D on NM_130785.3) | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.43); catalogued as COSV55019403; called by muse, mutect2
- TRIP10 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs920707723; called by muse, mutect2, varscan2
- UBE3C | c.2853G>T p.W951C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61955011; called by muse, mutect2, varscan2
- USP28 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs759816464; called by muse, mutect2, varscan2
- XKR6 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.771); catalogued as rs578022670, COSV58655993; called by muse, mutect2, varscan2
- ZBTB43 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100991276; called by muse, mutect2, varscan2
- ZFHX4 | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99269066; called by mutect2, varscan2
- AADACL2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AAGAB | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.087); called by muse, mutect2
- ABCA4 | c.3968G>T p.G1323V | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC126283.2 | c.1000C>A p.H334N | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.293); called by muse, mutect2
- ADAMTS13 | c.2058G>C p.W686C | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ADGRV1 | c.8284G>T p.E2762* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- AK8 | c.1396A>C p.I466L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- ALDH1A2 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AMPH | c.1807dup p.M603Nfs*5 | Frame Shift Ins (INS) | VAF 24/234 reads (10%) | called by pindel, varscan2
- ANK2 | c.7711G>T p.E2571* | Nonsense Mutation (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- ANK3 | c.9515C>G p.P3172R | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ANTXRL | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, varscan2
- ARHGAP27 | c.2058G>C p.E686D (on ENST00000428638 / NM_001282290.1; = p.E345D on NM_199282.3) | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- AVL9 | c.1514T>A p.I505N | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- BAG6 | c.1892G>C p.G631A (on ENST00000676571; = p.G584A on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCAS1 | c.1298A>T p.K433I | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- BRIX1 | c.44A>C p.Q15P | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.069); called by muse, mutect2
- CAMKK1 | c.211A>T p.R71W | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP97 | c.1658T>G p.V553G | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- CFAP46 | c.4944G>T p.L1648F | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHST13 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN5 | c.178G>C p.G60R (on ENST00000618236 / NM_001363066.2; = p.G145R on NM_003277.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNTN3 | c.1546A>G p.S516G | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- COL11A1 | c.3661C>A p.P1221T | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL6A3 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- CSMD1 | c.9250G>T p.G3084C (on ENST00000520002; = p.G3083C on NM_033225.6) | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, varscan2
- CYP3A4 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCAF12L2 | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- DCAF17 | c.321G>A p.V107= | Splice Region (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2, varscan2
- DLG2 | c.2162T>A p.V721E | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.445); called by muse, mutect2
- DNAH9 | c.7275G>T p.E2425D | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DOCK9 | c.4426G>T p.A1476S (on ENST00000376460 / NM_001366676.2; = p.A1477S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0); called by mutect2, varscan2
- DRP2 | c.2693C>G p.S898* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- ELL | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- F13A1 | c.371C>G p.S124* | Nonsense Mutation (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- FBXL7 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 113/423 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FKTN | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FOXJ2 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GBA | c.114A>G p.S38= | Splice Region (SNP) | VAF 42/516 reads (8%) | called by muse, mutect2
- GPR101 | c.429G>C p.M143I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HNRNPA1 | c.15+5G>T | Splice Region (SNP) | VAF 30/500 reads (6%) | called by muse, mutect2
- IGHV4-28 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 74/636 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, varscan2
- IL1RL2 | c.807G>T p.L269F | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2
- IMPG2 | c.2954A>T p.D985V | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- INTU | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 47/416 reads (11%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.379); called by muse, mutect2
- KIAA0319 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- KIAA1549 | c.4722G>C p.K1574N | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2C | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2
- LMAN1 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MAGEB6 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MAPRE1 | c.600C>G p.V200= | Splice Region (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- MATN2 | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- MDK | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, varscan2
- MECOM | c.1781G>C p.R594T (on ENST00000468789 / NM_001105078.4; = p.R782T on NM_004991.4) | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MINDY4B | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MRFAP1L1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- MUC19 | c.862G>T p.V288F | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); called by muse, varscan2
- MUC5B | c.1458C>A p.D486E | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, varscan2
- MYO16 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2
- MYOM1 | c.909G>T p.W303C | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- NBEAL2 | c.7113A>C p.E2371D | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCAPG2 | c.3014G>T p.R1005L | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NCKAP1L | c.2516C>A p.A839D | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- NDUFS3 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFE2L3 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- NLRP13 | c.3028C>A p.L1010M | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NXPH1 | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR10Z1 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- OR51T1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5T2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, varscan2
- OR8I2 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- OR8K1 | c.675G>C p.M225I | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX1 | c.3655C>G p.Q1219E | Missense Mutation (SNP) | VAF 52/494 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PIKFYVE | c.5718G>T p.R1906S | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.304); called by muse, mutect2
- PKHD1L1 | c.9234G>C p.W3078C | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- PLCL2 | c.2099T>C p.V700A (on ENST00000615277 / NM_001144382.2; = p.V574A on NM_015184.5) | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, varscan2
- PON3 | c.607T>G p.Y203D | Missense Mutation (SNP) | VAF 51/412 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POP1 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PPARGC1A | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | called by muse, varscan2
- PTPRQ | c.3001A>T p.N1001Y (on ENST00000616559; = p.N959Y on NM_001145026.2) | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RAP1B | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- RBSN | c.1017G>T p.L339F | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RELN | c.3289G>T p.G1097W | Missense Mutation (SNP) | VAF 71/485 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.10769T>G p.L3590R | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SARDH | c.2201G>T p.G734V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK1 | c.2059G>C p.V687L | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC24B | c.2433dup p.Q812Sfs*19 | Frame Shift Ins (INS) | VAF 42/363 reads (12%) | called by mutect2, pindel, varscan2
- SI | c.4075C>A p.H1359N | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- SIGLEC1 | c.2336A>T p.E779V | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SLC5A3 | c.1712G>T p.S571I | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC6A5 | c.1333G>T p.G445* | Nonsense Mutation (SNP) | VAF 50/418 reads (12%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 52/415 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLX4 | c.4547G>A p.G1516E | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.043); called by muse, mutect2
- SNX7 | c.1119_1125+10del p.X373_splice | Splice Site (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel
- SPATA31A6 | c.1146C>A p.F382L | Missense Mutation (SNP) | VAF 94/453 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- SPTA1 | c.7214C>G p.S2405C | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2
- SRCAP | c.2213A>G p.K738R | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- STPG2 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 18/168 reads (11%) | called by muse, varscan2
- STT3A | c.1430G>T p.W477L | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SUFU | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYNE1 | c.24138G>C p.Q8046H (on ENST00000367255 / NM_182961.4; = p.Q7975H on NM_033071.3) | Missense Mutation (SNP) | VAF 19/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TANC1 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- TIGD5 | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TJP1 | c.3961A>G p.K1321E | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by mutect2, varscan2
- TRIM46 | c.978G>C p.E326D | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- TRIM50 | c.519G>T p.W173C | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TRPM1 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 56/730 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2
- TTN | c.23382G>C p.W7794C (on ENST00000591111; = p.W6867C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/198 reads (10%) | PolyPhen benign (0.167); called by muse, varscan2
- TYR | c.1006del p.A336Pfs*19 | Frame Shift Del (DEL) | VAF 34/336 reads (10%) | called by pindel, varscan2
- UBA6 | c.168G>T p.M56I | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- USP38 | c.1379dup p.Q461Tfs*50 | Frame Shift Ins (INS) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- VPS35 | c.1596G>T p.L532F | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- WDR64 | c.1810G>T p.G604W | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- WWC2 | c.353A>T p.Y118F | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2
- XRN2 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZFHX4 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZIC3 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF10 | c.1027C>G p.H343D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF550 | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2
- ACP7 | c.1020G>A p.L340= | Silent (SNP) | VAF 23/208 reads (11%) | called by muse, mutect2, varscan2
- ADAM7 | c.489G>T p.P163= | Silent (SNP) | VAF 38/311 reads (12%) | catalogued as rs776521318, COSV51540515; called by muse, mutect2, varscan2
- ARMCX5 | c.906A>C p.S302= | Silent (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- ATP6V1A | c.1833A>G p.A611= | Silent (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- CD1A | c.645C>A p.G215= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs1474470896, COSV56860384; called by muse, mutect2
- CD1C | c.798G>T p.V266= | Silent (SNP) | VAF 19/373 reads (5%) | called by muse, mutect2
- COL4A1 | c.1557G>T p.G519= | Silent (SNP) | VAF 51/284 reads (18%) | called by muse, mutect2, varscan2
- DCBLD1 | c.177C>T p.P59= | Silent (SNP) | VAF 65/443 reads (15%) | catalogued as rs759068929; called by muse, mutect2, varscan2
- DDC | c.1401C>T p.I467= | Silent (SNP) | VAF 57/391 reads (15%) | called by muse, mutect2, varscan2
- DGAT2L6 | c.186C>T p.T62= | Silent (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- DNAJC24 | c.48G>T p.L16= | Silent (SNP) | VAF 26/267 reads (10%) | called by muse, mutect2
- DOCK4 | c.2491C>T p.L831= | Silent (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- DRP2 | c.2863C>T p.L955= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, varscan2
- DUS3L | c.657G>C p.R219= | Silent (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- EMILIN2 | c.1476G>A p.Q492= | Silent (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- FAM163B | c.48G>A p.V16= | Silent (SNP) | VAF 38/275 reads (14%) | called by muse, mutect2, varscan2
- FOXR2 | c.96G>T p.L32= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV59259338; called by muse, mutect2
- GAR1 | c.582A>G p.R194= | Silent (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- GOLGA6L2 | c.1269G>T p.V423= | Silent (SNP) | VAF 26/444 reads (6%) | called by muse, mutect2
- HS2ST1 | c.1065G>A p.S355= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs774069358, COSV100777709; called by muse, mutect2, varscan2
- HTR6 | c.741G>A p.V247= | Silent (SNP) | VAF 22/431 reads (5%) | catalogued as rs1425606938; called by muse, mutect2
- IFT80 | c.723A>G p.G241= | Silent (SNP) | VAF 48/546 reads (9%) | catalogued as rs1559957667; called by muse, mutect2
- IQCB1 | c.999A>T p.S333= | Silent (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- LRIT1 | c.981C>T p.I327= | Silent (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- LRRTM4 | c.1437C>T p.S479= | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- NCKAP1L | c.2517C>G p.A839= | Silent (SNP) | VAF 36/184 reads (20%) | called by muse, mutect2, varscan2
- NOTCH3 | c.3870G>T p.A1290= | Silent (SNP) | VAF 24/163 reads (15%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.345G>T p.L115= | Silent (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- OR56B1 | c.765C>T p.T255= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV57723032; called by muse, mutect2, varscan2
- PI4KA | c.951C>T p.V317= | Silent (SNP) | VAF 32/235 reads (14%) | called by muse, varscan2
- PLCL2 | c.2121A>G p.P707= (on ENST00000615277 / NM_001144382.2; = p.P581= on NM_015184.5) | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, varscan2
- PMFBP1 | c.1065G>T p.L355= | Silent (SNP) | VAF 12/169 reads (7%) | called by muse, mutect2
- PRDM9 | c.720C>G p.L240= | Silent (SNP) | VAF 61/682 reads (9%) | called by muse, mutect2
- RTCB | c.348C>G p.V116= | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1365G>A p.E455= (on ENST00000265814 / NM_001198628.1; = p.E428= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1283008384; called by muse, mutect2, varscan2
- SCART1 | c.1503G>T p.V501= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- SHANK1 | c.903G>T p.L301= | Silent (SNP) | VAF 38/303 reads (13%) | catalogued as COSV53262606; called by muse, mutect2, varscan2
- SLC5A4 | c.1917A>T p.I639= | Silent (SNP) | VAF 42/283 reads (15%) | called by muse, mutect2, varscan2
- SLC9A4 | c.333C>A p.G111= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs375903377, COSV54834628; called by muse, mutect2, varscan2
- STXBP5L | c.2868A>G p.K956= | Silent (SNP) | VAF 42/328 reads (13%) | catalogued as rs751243877; called by muse, varscan2
- SVEP1 | c.195C>T p.G65= | Silent (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- SYNJ2 | c.3357G>A p.V1119= | Silent (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- TAF4 | c.3009C>T p.D1003= | Silent (SNP) | VAF 29/190 reads (15%) | catalogued as rs764509413, COSV99434782; called by muse, mutect2, varscan2
- TRHDE | c.999C>A p.A333= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as COSV99670987; called by muse, varscan2
- USP26 | c.1368C>A p.L456= | Silent (SNP) | VAF 51/227 reads (22%) | catalogued as COSV100896716; called by muse, mutect2, varscan2
- WFDC8 | c.546T>C p.C182= | Silent (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- ZNF416 | c.330C>G p.V110= | Silent (SNP) | VAF 13/364 reads (4%) | called by muse, mutect2
- ABI3BP | c.1576+11662G>C | Intron (SNP) | VAF 32/305 reads (10%) | called by muse, mutect2, varscan2
- AC098591.2 | n.1191G>A | RNA (SNP) | VAF 26/290 reads (9%) | catalogued as rs1329344034; called by muse, mutect2
- AC136628.2 | n.227C>A | RNA (SNP) | VAF 41/173 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.634+48T>C | Intron (SNP) | VAF 22/224 reads (10%) | catalogued as rs764190455; called by muse, mutect2
- ADTRP | c.*30G>C | 3'UTR (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- AGBL3 | c.2110+12654C>T | Intron (SNP) | VAF 32/434 reads (7%) | called by muse, mutect2
- ANK1 | c.5619+243C>A | Intron (SNP) | VAF 42/249 reads (17%) | called by muse, mutect2, varscan2
- CDH8 | c.*5738T>A | 3'UTR (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- CHRDL2 | c.1120+1174G>A | Intron (SNP) | VAF 31/224 reads (14%) | called by muse, mutect2, varscan2
- CTHRC1 | c.150+734C>A | Intron (SNP) | VAF 36/194 reads (19%) | called by muse, mutect2, varscan2
- DHX38 | c.*295G>A | 3'UTR (SNP) | VAF 48/335 reads (14%) | catalogued as rs748104333; called by muse, mutect2, varscan2
- DLG5 | c.373+2071T>G | Intron (SNP) | VAF 31/247 reads (13%) | called by muse, mutect2, varscan2
- DZIP1L | c.2142+69_2142+91del | Intron (DEL) | VAF 9/113 reads (8%) | called by mutect2, pindel
- FAM90A27P | n.5C>A | RNA (SNP) | VAF 14/153 reads (9%) | called by muse, mutect2
- GDA | c.-34G>T | 5'UTR (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- HLA-DPB1 | c.101-162G>A | Intron (SNP) | VAF 37/605 reads (6%) | called by muse, mutect2
- LRIG1 | c.1161-2595C>T | Intron (SNP) | VAF 20/112 reads (18%) | catalogued as rs1404175892; called by muse, varscan2
- MAN1B1 | c.*319C>T | 3'UTR (SNP) | VAF 38/283 reads (13%) | catalogued as rs1195872438; called by muse, mutect2, varscan2
- NCR2 | c.-48A>T | 5'UTR (SNP) | VAF 27/238 reads (11%) | called by muse, mutect2, varscan2
- PASK | c.1307-22T>G | Intron (SNP) | VAF 16/293 reads (5%) | called by muse, mutect2
- RALB | c.114+2089A>C | Intron (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- TAF6L | c.-14+623C>G | Intron (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- TMEM26 | c.682+484G>C | Intron (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- TPO | c.2748+114C>A | Intron (SNP) | VAF 49/222 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.10360+1601G>A | Intron (SNP) | VAF 10/107 reads (9%) | catalogued as COSV100611908, COSV100623566; called by muse, mutect2
- TYR | c.*22G>T | 3'UTR (SNP) | VAF 30/251 reads (12%) | called by muse, mutect2, varscan2
- UROS | c.*43G>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- VSIG10L2 | chr11:125943045 C>G | 5'Flank (SNP) | VAF 45/260 reads (17%) | catalogued as rs1241199685; called by muse, mutect2, varscan2
